Somatic mutation profile of tumor specimen TCGA-AJ-A3BD-01A (aliquot TCGA-AJ-A3BD-01A-11D-A19Y-09) from TCGA case TCGA-AJ-A3BD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 57.5 years (20,998 days).
Specimen TCGA-AJ-A3BD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8004206-48aa-49c6-90ad-ebbdcb3143ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3BD-10A (Blood Derived Normal), aliquot TCGA-AJ-A3BD-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f39b909-24a2-46e6-9fb0-27cae4c6105a

The open-access MAF lists 73 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 13, Splice Site 2, Splice Region 2, In Frame Del 1, Intron 1, Frame Shift Ins 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 68/106 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 31/43 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC008397.2 | c.1819C>A p.P607T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99441698; called by muse, mutect2, varscan2
- ADCY10 | c.4024C>T p.L1342F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100896854; called by muse, mutect2, varscan2
- ADGRA3 | c.2192C>A p.T731K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99293285; called by muse, mutect2
- BCORL1 | c.3490A>G p.R1164G | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99499488; called by muse, mutect2
- CACNA2D4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs375121955, COSV54944517; called by muse, mutect2, varscan2
- CHDH | c.777G>C p.E259D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100179699; called by muse, mutect2, varscan2
- CLCA1 | c.1471A>C p.S491R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99322366; called by muse, mutect2
- CLEC16A | c.556G>T p.V186F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101278060; called by muse, mutect2
- COMTD1 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748345837, COSV100040959; called by muse, mutect2, varscan2
- CYP27B1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs772898470, COSV99141570; called by muse, mutect2, varscan2
- DCAF1 | c.3622G>A p.G1208S | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1553629762, COSV100244440; called by muse, mutect2, varscan2
- DCN | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV50006179, COSV50008176; called by muse, mutect2, varscan2
- DNAJC6 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as rs769067430, COSV99674843; called by muse, mutect2, varscan2
- DNAL4 | c.154-1G>C p.X52_splice | Splice Site (SNP) | VAF 10/75 reads (13%) | catalogued as COSV99326120; called by muse, mutect2, varscan2
- DOP1B | c.2553G>C p.Q851H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101214956; called by muse, mutect2, varscan2
- DVL1 | c.467C>G p.A156G | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.478); catalogued as COSV101127471; called by muse, mutect2, varscan2
- FSCB | c.2039C>A p.A680D | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV100469335; called by muse, mutect2, varscan2
- GPRC5C | c.1281G>A p.P427= (on ENST00000652232; = p.P382= on NM_018653.4) | Splice Region (SNP) | VAF 12/45 reads (27%) | catalogued as rs376775597, COSV100702890; called by muse, mutect2, varscan2
- GRIN2B | c.1994G>T p.G665V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101663036, COSV74205416; called by muse, mutect2, varscan2
- GUCY1A1 | c.2042A>T p.N681I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1554004221, COSV99637760; called by muse, mutect2, varscan2
- HOXC9 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV100327476; called by muse, mutect2, varscan2
- IGSF21 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs770457601, COSV52132239, COSV99244507; called by muse, mutect2, varscan2
- IGSF9B | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV100317653, COSV58063986; called by muse, mutect2, varscan2
- IL12RB2 | c.2525T>G p.F842C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99255074; called by muse, mutect2, varscan2
- INPP5B | c.2422G>C p.E808Q (on ENST00000373023; = p.E728Q on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100886487; called by muse, mutect2, varscan2
- KRT33B | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs755963947, COSV99290634; called by muse, mutect2, varscan2
- L3MBTL2 | c.1705C>A p.H569N | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV99345893; called by muse, mutect2, varscan2
- MCM3AP | c.3322G>T p.A1108S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.058); catalogued as COSV99386961; called by muse, mutect2, varscan2
- MGAT4B | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1047960020, COSV52977482; called by muse, mutect2, varscan2
- MS4A5 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs776223801, COSV100281003; called by muse, mutect2, varscan2
- NAV3 | c.4768T>C p.S1590P | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99891018; called by muse, mutect2, varscan2
- NCOA6 | c.3371C>T p.S1124L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1157478730, COSV100750042; called by muse, mutect2, varscan2
- NCOR2 | c.4685C>T p.T1562M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as rs1455571371, COSV100657335; called by muse, mutect2, varscan2
- OR4K14 | c.213C>A p.D71E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV100520430; called by muse, mutect2
- P2RX4 | c.426C>T p.N142= | Splice Region (SNP) | VAF 12/56 reads (21%) | catalogued as rs757649990, COSV100078729; called by muse, mutect2, varscan2
- PCDH12 | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143217665; called by muse, mutect2, varscan2
- PCDHB12 | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV99507268; called by muse, mutect2, varscan2
- PNLIPRP3 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100982483, COSV65048755; called by muse, mutect2
- PREB | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1272774755, COSV53207765; called by muse, mutect2, varscan2
- PSD | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV99192704; called by muse, mutect2, varscan2
- RNF32 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100311408; called by muse, mutect2, varscan2
- RPL7L1 | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100491699, COSV59034403; called by muse, mutect2
- SIGLEC6 | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV100585390; called by muse, mutect2, varscan2
- SLC4A11 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV101195973; called by mutect2, varscan2
- SLCO4A1 | c.107G>A p.G36D | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1284778742, COSV99414747; called by muse, mutect2, varscan2
- SOX9 | c.1364C>G p.A455G | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.818); catalogued as COSV99818441; called by muse, mutect2, varscan2
- SPHKAP | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs754224869, COSV60884372; called by muse, mutect2, varscan2
- TRIM40 | c.269G>A p.C90Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100325358; called by muse, mutect2
- TTBK1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs866390871, COSV52492536; called by muse, mutect2
- UBE4A | c.2588-1G>C p.X863_splice (on ENST00000252108 / NM_001204077.2; = p.X870_splice on NM_004788.4) | Splice Site (SNP) | VAF 5/39 reads (13%) | catalogued as COSV52807743, COSV99347891; called by muse, mutect2, varscan2
- ZNF205 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99530400; called by muse, mutect2
- ZNF280C | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100921231; called by muse, mutect2, varscan2
- ZNF57 | c.1433G>A p.C478Y | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV100182905; called by muse, mutect2, varscan2
- CAND1 | c.3056_3057dup p.L1020Ifs*2 | Frame Shift Ins (INS) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- PCSK9 | c.293_316del p.L98_G106delinsR | In Frame Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- PRPF8 | c.5642_5650dup p.N1881_V1883dup | In Frame Ins (INS) | VAF 32/50 reads (64%) | called by mutect2, varscan2
- ARL4C | c.384G>A p.K128= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs764670514, COSV100326937; called by mutect2, varscan2
- HOMER2 | c.81G>C p.A27= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs746027391, COSV100420355, COSV58485505; called by muse, mutect2, varscan2
- IL13RA1 | c.711C>T p.S237= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100861721; called by muse, mutect2, varscan2
- MAN1A2 | c.882G>A p.L294= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs1190466881, COSV100740930; called by muse, mutect2, varscan2
- MICALL1 | c.1734C>T p.S578= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99317272; called by muse, mutect2, varscan2
- MST1 | c.2127G>A p.T709= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as rs369736713, COSV99610782; called by muse, mutect2, varscan2
- PHKA2 | c.201C>T p.R67= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs746817651, COSV66055430; called by muse, mutect2, varscan2
- PLEKHG3 | c.2256C>T p.F752= (on ENST00000394691; = p.F808= on NM_001308147.2) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99906609; called by muse, mutect2, varscan2
- SDK1 | c.5241G>A p.Q1747= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs148337133; called by muse, mutect2, varscan2
- SLC9A4 | c.846C>A p.I282= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV54834011, COSV99763034; called by muse, mutect2, varscan2
- TENM1 | c.6537C>T p.N2179= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100950050; called by muse, mutect2, varscan2
- VIPR1 | c.417C>T p.Y139= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1297692879, COSV100285542; called by muse, mutect2, varscan2
- ZNF473 | c.435G>A p.T145= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs553519000, COSV99568827; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 8/66 reads (12%) | catalogued as rs201441562; called by pindel, varscan2
